Gene-level copy-number profile of tumor specimen MP2PRT-PASKFJ-TMP1-A from MP2PRT case MP2PRT-PASKFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,490 days).
Specimen MP2PRT-PASKFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e3b718e0-3a75-46bb-93a8-ea87089ac46b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASKFJ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/269121f6-6a76-4793-be3f-11d61267dd27

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 864; copy number 2: 40,594; copy number 3: 15,293; copy number 4: 2,055; copy number 5: 82.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,045,995–89,085,787, 3 genes (within-gene range 0–1): IGKV1-13, IGKV2-14, IGKV3-15.
- chr2:89,128,724–89,135,257, 2 genes (within-gene range 0–1): IGKV2-18, IGKV2-19.
- chr2:89,252,211–89,295,455, 6 genes: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr16:32,379,071–32,460,362, 5 genes: ACTR3BP3, AC138915.2, PABPC1P13, AC138915.3, AC138915.1.
- chr16:32,635,673–32,636,045, 1 gene: AC133569.1.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 82 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,841,240–22,272,563, 42 genes, copy number 5: TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1.
- chr14:105,620,506–105,669,843, 6 genes, copy number 5 (within-gene range 4–5): IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP.
- chr14:106,643,142–106,652,681, 3 genes, copy number 5 (within-gene range 4–5): IGHV3-62, IGHVII-62-1, IGHV3-63.
- chr14:106,675,017–106,879,812, 26 genes, copy number 5 (within-gene range 4–5): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr21:44,107,373–44,210,114, 5 genes, copy number 5 (within-gene range 3–5): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
